Somatic mutation profile of tumor specimen TCGA-AG-3574-01A (aliquot TCGA-AG-3574-01A-01D-1989-10) from TCGA case TCGA-AG-3574, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AG-3574-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23959c89-ee36-4e00-b20f-21f1278047b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3574-10A (Blood Derived Normal), aliquot TCGA-AG-3574-10A-01D-1989-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ad81070-10ee-4a7f-9db2-9997d7ddf40a

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP1 | c.11383G>A p.E3795K | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs773744975, COSV54503674; called by muse, mutect2, varscan2
- PLXNB3 | c.4345A>T p.M1449L | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV100737514; called by muse, mutect2, varscan2
- REEP4 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as rs778549491, COSV57942617; called by muse, varscan2
- ZSCAN18 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.203); catalogued as rs368350026; called by muse, mutect2, varscan2
- KCNA4 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- RNPEPL1 | c.1572_1573dup p.Q525Lfs*6 | Frame Shift Ins (INS) | VAF 34/81 reads (42%) | called by mutect2, pindel, varscan2
- VEGFC | c.813C>A p.D271E | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XIRP2 | c.1916C>T p.T639I (on ENST00000628543; = p.T814I on NM_152381.6) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHA8 | c.471G>A p.A157= | Silent (SNP) | VAF 123/255 reads (48%) | called by muse, mutect2, varscan2
- SLC2A5 | c.963C>T p.T321= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1236412300, COSV101072662; called by muse, varscan2
